CCDI case PBCTYK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/838bf354-ed4f-4cab-84f9-3af2f29ef6d8

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 14.9 years (5,426 days).

Biospecimens (3 samples)
- Sample 0DZTYR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZU05: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DZU0W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
